Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4CS, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4CS-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy

Tumor site: Fundus

Tumor size: 5 x 4 x 1.5 cm

Tumor features: None specified

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Adjacent structures (specify) - Greater omentum

Lymph nodes: 7/15 positive for metastasis (Intraabdominal 7/15)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: stomach, fundus C16.1
lw
9/27/12

lw
9/13/12

Source: NCI Genomic Data Commons file 602e4778-ff88-4382-bbf6-be81f1cd825f (TCGA-BR-A4CS.43050057-F3ED-4C99-B6F6-624CAFC6F6D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).